TCGA case TCGA-24-1416 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f9793a4b-c0e7-4475-bf80-69543b7ee2f6

Demographics
Sex at birth: female; Race: white; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 35.0 years (12,772 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 194 days.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 170 days; Number of cycles: 8; Treatment dose: 422 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 170 days; Number of cycles: 8; Treatment dose: 946 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 170 days; Number of cycles: 8; Treatment dose: 934 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 170 days; Number of cycles: 8; Treatment dose: 647 mg; Route of administration: Intraperitoneal / Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 194 days; Disease response: Tumor Free.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-24-1416-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 25; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-24-1416-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-24-1416-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IP; Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 194 days; disease-specific survival: no event (censored), 194 days; progression-free interval: no event (censored), 194 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1416-01A-01D-0472-01): tumor purity 0.82, ploidy 3.7, whole-genome doublings 1.
